Somatic mutation profile of tumor specimen TCGA-HZ-8005-01A (aliquot TCGA-HZ-8005-01A-11D-2201-08) from TCGA case TCGA-HZ-8005, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 81.2 years (29,674 days).
Specimen TCGA-HZ-8005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8e0a9c21-d73d-4703-abe9-c63e0072ca33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-8005-10A (Blood Derived Normal), aliquot TCGA-HZ-8005-10A-01D-2201-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a2c4c929-c10c-4e2f-91fc-b74e9bc71d45

The open-access MAF lists 60 somatic variants for this specimen: 46 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 13, Frame Shift Del 4, Nonsense Mutation 2, Splice Site 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 114/429 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.993+1G>A p.X331_splice | Splice Site (SNP) | VAF 64/394 reads (16%) | hotspot (GDC flag); catalogued as rs11575997, CD002536, COSV52663229, COSV52699909, COSV52752826; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACE | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 164/813 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.643); catalogued as COSV99327104; called by muse, mutect2, varscan2
- ACTL9 | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 92/606 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV100185365; called by muse, mutect2, varscan2
- ADGRL4 | c.1241C>A p.S414Y | Missense Mutation (SNP) | VAF 70/683 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100876043; called by muse, mutect2, varscan2
- AHR | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 159/836 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.779); catalogued as COSV54121537, COSV99619757; called by muse, mutect2, varscan2
- APOB | c.3406G>T p.E1136* | Nonsense Mutation (SNP) | VAF 38/592 reads (6%) | catalogued as COSV99265872; called by muse, mutect2
- AREL1 | c.1693G>C p.E565Q | Missense Mutation (SNP) | VAF 68/812 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100707616; called by muse, mutect2
- CALN1 | c.586G>A p.A196T (on ENST00000329008 / NM_001017440.3; = p.A238T on NM_031468.4) | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770151080, COSV61117552; called by muse, mutect2
- CNGA4 | c.1387A>G p.I463V | Missense Mutation (SNP) | VAF 155/579 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs202038469, COSV101171809; called by muse, mutect2, varscan2
- DAAM1 | c.2369T>C p.V790A | Missense Mutation (SNP) | VAF 51/238 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.241); catalogued as COSV100658441, COSV62834277; called by muse, mutect2, varscan2
- DENND5A | c.3104T>C p.I1035T | Missense Mutation (SNP) | VAF 154/985 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as COSV100064753; called by muse, mutect2, varscan2
- DYRK1A | c.1191G>T p.K397N | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV100117914; called by muse, mutect2, varscan2
- ENY2 | c.7-1G>A p.X3_splice | Splice Site (SNP) | VAF 34/220 reads (15%) | catalogued as COSV99517204; called by muse, mutect2, varscan2
- ERBB4 | c.896T>A p.V299E | Missense Mutation (SNP) | VAF 46/282 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53521707, COSV99624687; called by muse, mutect2, varscan2
- KIF17 | c.841C>T p.R281C | Missense Mutation (SNP) | VAF 75/734 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs746439314, COSV99929134; called by muse, mutect2, varscan2
- LGR6 | c.1021C>T p.R341W (on ENST00000367278 / NM_001017403.1; = p.R289W on NM_021636.3) | Missense Mutation (SNP) | VAF 28/407 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs755009342, COSV99707080; called by muse, mutect2
- LHFPL2 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 29/165 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs1472802663, COSV100982548; called by muse, mutect2, varscan2
- MCM2 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 361/1273 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766530339, COSV99413180; called by muse, mutect2, varscan2
- MYH4 | c.2507T>C p.L836P | Missense Mutation (SNP) | VAF 107/568 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1567701999, COSV99701386; called by muse, mutect2, varscan2
- NFAM1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 84/1816 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as rs145224229, COSV61194700; called by muse, mutect2
- NPY5R | c.991C>A p.P331T | Missense Mutation (SNP) | VAF 84/344 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV100642792; called by muse, mutect2, varscan2
- ODF1 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 138/2000 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.932); catalogued as COSV99574217; called by muse, mutect2
- OR10G9 | c.754G>A p.V252I | Missense Mutation (SNP) | VAF 129/745 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100901624; called by muse, mutect2, varscan2
- OR4S1 | c.652A>G p.I218V | Missense Mutation (SNP) | VAF 77/738 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100180251; called by muse, mutect2, varscan2
- PCDH15 | c.4790G>T p.S1597I (on ENST00000644397 / NM_001354429.2; = p.S1539I on NM_001142771.2) | Missense Mutation (SNP) | VAF 26/286 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.152); catalogued as COSV100904643, COSV100905639; called by muse, mutect2
- PPIL1 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 80/347 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs755572189, COSV65472487; called by muse, mutect2, varscan2
- PPP2R1B | c.1109A>G p.K370R | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV100232189; called by muse, mutect2, varscan2
- PRIMA1 | c.200C>T p.P67L | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1440739420, COSV60265410; called by muse, mutect2
- PSD | c.2933C>T p.A978V | Missense Mutation (SNP) | VAF 34/478 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.071); catalogued as rs572223815, COSV50044399; called by muse, mutect2
- PTCH2 | c.1277G>A p.G426D | Missense Mutation (SNP) | VAF 70/307 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100942118; called by muse, mutect2, varscan2
- PTPRS | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 94/523 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1351608223, COSV99510817; called by muse, mutect2, varscan2
- RANBP3 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 22/297 reads (7%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.983); catalogued as COSV99222310; called by muse, mutect2
- SEC31B | c.2872C>T p.P958S | Missense Mutation (SNP) | VAF 115/611 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as COSV100947330; called by muse, mutect2, varscan2
- SPTA1 | c.3668G>A p.R1223Q | Missense Mutation (SNP) | VAF 69/633 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148714399, COSV63754963; called by muse, mutect2, varscan2
- STAU2 | c.938C>T p.A313V (on ENST00000524300 / NM_001164380.2; = p.A281V on NM_014393.2) | Missense Mutation (SNP) | VAF 94/384 reads (24%) | SIFT tolerated (0.85); PolyPhen probably damaging (0.932); catalogued as rs752254966, COSV100869115; called by muse, mutect2, varscan2
- TENM3 | c.5227G>A p.G1743S | Missense Mutation (SNP) | VAF 94/442 reads (21%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs368953698; called by muse, mutect2, varscan2
- TOR1AIP1 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 66/358 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.043); catalogued as COSV99621357; called by muse, mutect2, varscan2
- TTI1 | c.966T>G p.S322R | Missense Mutation (SNP) | VAF 255/921 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV100989642; called by muse, mutect2, varscan2
- WNK4 | c.2008C>T p.R670C | Missense Mutation (SNP) | VAF 56/303 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746440189, COSV55906679; called by muse, mutect2, varscan2
- ZFHX3 | c.3313C>T p.Q1105* | Nonsense Mutation (SNP) | VAF 47/364 reads (13%) | catalogued as COSV99212864; called by muse, mutect2, varscan2
- MAP1LC3A | c.268_271del p.S90Cfs*57 | Frame Shift Del (DEL) | VAF 193/726 reads (27%) | called by mutect2, pindel, varscan2
- MRPS30 | c.1263_1272del p.V422Yfs*2 | Frame Shift Del (DEL) | VAF 28/228 reads (12%) | called by mutect2, pindel
- NCOA2 | c.1061_1064del p.K354Tfs*13 | Frame Shift Del (DEL) | VAF 170/829 reads (21%) | called by mutect2, pindel, varscan2
- ROCK1 | c.1146del p.I383Ffs*13 | Frame Shift Del (DEL) | VAF 88/582 reads (15%) | called by mutect2, pindel, varscan2
- RSRC2 | c.208-8del | Splice Region (DEL) | VAF 75/340 reads (22%) | called by mutect2, pindel, varscan2
- ASTN1 | c.636C>T p.H212= | Silent (SNP) | VAF 49/486 reads (10%) | catalogued as rs907788829, COSV56062191, COSV56088457; called by muse, mutect2
- CDH8 | c.399C>T p.T133= | Silent (SNP) | VAF 103/759 reads (14%) | catalogued as COSV100181832, COSV54878650; called by muse, mutect2, varscan2
- EXD2 | c.1530C>T p.L510= (on ENST00000312994 / NM_001193362.1; = p.L385= on NM_018199.3) | Silent (SNP) | VAF 13/181 reads (7%) | catalogued as COSV100474137; called by muse, mutect2
- GPRASP1 | c.1239C>T p.D413= | Silent (SNP) | VAF 115/367 reads (31%) | catalogued as rs144058687, COSV64355148, COSV64355300; called by muse, mutect2, varscan2
- HSP90AA1 | c.282T>A p.T94= | Silent (SNP) | VAF 71/510 reads (14%) | catalogued as COSV99355315; called by muse, mutect2, varscan2
- KRT84 | c.363C>G p.G121= | Silent (SNP) | VAF 100/1314 reads (8%) | catalogued as COSV99230897; called by muse, mutect2
- MIB2 | c.2952C>T p.V984= | Silent (SNP) | VAF 36/194 reads (19%) | catalogued as rs1447437097, COSV100598924; called by muse, mutect2, varscan2
- RNF182 | c.189C>G p.V63= | Silent (SNP) | VAF 168/1035 reads (16%) | catalogued as COSV101337910; called by muse, mutect2, varscan2
- RP1 | c.5349A>G p.V1783= | Silent (SNP) | VAF 13/284 reads (5%) | catalogued as rs1315876788, COSV99607632; called by muse, mutect2
- TENM4 | c.5871G>A p.T1957= | Silent (SNP) | VAF 69/431 reads (16%) | catalogued as rs201865895, COSV53672830; called by muse, mutect2, varscan2
- TLR4 | c.672A>G p.K224= (on ENST00000355622 / NM_138554.5; = p.K184= on NM_003266.4) | Silent (SNP) | VAF 39/425 reads (9%) | catalogued as COSV100790652; called by muse, mutect2
- TRAV9-2 | c.129G>A p.T43= | Silent (SNP) | VAF 53/247 reads (21%) | catalogued as rs369545967; called by muse, mutect2, varscan2
- ZIC1 | c.465G>A p.S155= | Silent (SNP) | VAF 57/165 reads (35%) | catalogued as rs376476564, COSV51553667; called by muse, mutect2, varscan2
- NACA | c.71-2294C>G | Intron (SNP) | VAF 46/752 reads (6%) | catalogued as COSV100771358; called by muse, mutect2
